Somatic mutation profile of tumor specimen TCGA-WB-A80N-01A (aliquot TCGA-WB-A80N-01A-11D-A35I-08) from TCGA case TCGA-WB-A80N, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 54.7 years (19,980 days).
Specimen TCGA-WB-A80N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b64994a-20a7-4867-8773-a1c96c1b7662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80N-10A (Blood Derived Normal), aliquot TCGA-WB-A80N-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3ece8ac-5ff0-4b3a-a61d-f4c63719827b

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERCC3 | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1371373080; called by muse, mutect2, varscan2
- IL21 | c.152A>C p.N51T | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.028); catalogued as COSV52647178; called by muse, mutect2, varscan2
- ZNF311 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1412226774; called by muse, mutect2, varscan2
- LRRN1 | c.2147G>T p.W716L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NT5C3A | c.692C>T p.T231I (on ENST00000610140 / NM_001374335.1; = p.T197I on NM_016489.13) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2
- SIGLEC6 | c.644G>C p.C215S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG8 | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABRAXAS2 | c.1017T>C p.S339= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- CDH16 | c.2473C>T p.L825= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
